Somatic mutation profile of tumor specimen TCGA-DF-A2L0-01A (aliquot TCGA-DF-A2L0-01A-11D-A17W-09) from TCGA case TCGA-DF-A2L0, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3.
Specimen TCGA-DF-A2L0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49331822-f238-47a4-b75e-ccb41377751d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DF-A2L0-10A (Blood Derived Normal), aliquot TCGA-DF-A2L0-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12161025-862a-4c4a-a52e-2c857831b7d5

The open-access MAF lists 50 somatic variants for this specimen: 40 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 30, Silent 10, Frame Shift Del 4, Splice Site 2, Nonsense Mutation 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 73/93 reads (78%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.644G>T p.S215I | Missense Mutation (SNP) | VAF 44/70 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782177, COSV52679681, COSV52686793, COSV52700292, COSV52891297; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.742G>T p.V248L | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.114); catalogued as COSV100318968; called by muse, mutect2, varscan2
- BCAN | c.761A>C p.D254A | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV100228503; called by muse, mutect2, varscan2
- BHMT | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 59/79 reads (75%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.731); catalogued as COSV99165533; called by muse, mutect2, varscan2
- BRIP1 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs1555615763, COSV99371106; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK5RAP1 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100212306; called by muse, mutect2, varscan2
- COL5A2 | c.1276G>A p.G426S | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100879988, COSV100880820; called by muse, mutect2, varscan2
- CTNND1 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as rs759024257, COSV100650286; called by muse, mutect2, varscan2
- DCX | c.862C>G p.P288A | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100576759; called by muse, mutect2, varscan2
- DGKK | c.3410T>A p.I1137N | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV101053214; called by muse, mutect2, varscan2
- DNAH2 | c.4484G>A p.R1495Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as rs145619879; called by muse, varscan2
- EGFR | c.1606G>A p.V536M | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs767193132, COSV51809160; called by muse, mutect2, varscan2
- F8 | c.5508G>A p.W1836* | Nonsense Mutation (SNP) | VAF 50/133 reads (38%) | catalogued as CM057453, COSV100811967; called by muse, mutect2, varscan2
- HAUS5 | c.675G>T p.Q225H | Missense Mutation (SNP) | VAF 65/93 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV99178829; called by muse, mutect2, varscan2
- JADE2 | c.2078T>G p.V693G | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV99253633; called by muse, mutect2, varscan2
- LBR | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99687739; called by muse, mutect2, varscan2
- MECOM | c.2004T>G p.F668L (on ENST00000468789 / NM_001105078.4; = p.F856L on NM_004991.4) | Missense Mutation (SNP) | VAF 74/544 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV99245445; called by muse, mutect2, varscan2
- NPY2R | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT tolerated (0.12); PolyPhen benign (0.118); catalogued as COSV100279923; called by muse, mutect2, varscan2
- P2RX4 | c.333G>C p.Q111H | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100078783; called by muse, mutect2, varscan2
- PCDHGB5 | c.452G>C p.R151T | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV53922713; called by muse, mutect2, varscan2
- PIK3R1 | c.1299+2T>C p.X433_splice (on ENST00000521381 / NM_181523.3; = p.X163_splice on NM_181504.4) | Splice Site (SNP) | VAF 8/14 reads (57%) | catalogued as COSV57127442; called by muse, mutect2, varscan2
- PTEN | c.366T>G p.I122M | Missense Mutation (SNP) | VAF 94/111 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100910521, COSV100911341; called by muse, mutect2, varscan2
- RNF43 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 49/70 reads (70%) | catalogued as COSV68456879, COSV68457530; called by muse, mutect2, varscan2
- RPS6KC1 | c.3113A>G p.E1038G | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100874099; called by muse, mutect2, varscan2
- SLC4A10 | c.2650C>G p.H884D (on ENST00000446997 / NM_001354461.2; = p.H854D on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55766526, COSV99765761; called by muse, mutect2, varscan2
- SLC8A3 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374224410; called by muse, mutect2, varscan2
- SMARCA1 | c.2698+1G>T p.X900_splice | Splice Site (SNP) | VAF 38/109 reads (35%) | catalogued as COSV100946720; called by muse, mutect2, varscan2
- TBX22 | c.1039A>C p.M347L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100960955; called by muse, mutect2, varscan2
- TRAF5 | c.593A>G p.N198S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1225454228, COSV99807630; called by muse, mutect2, varscan2
- TRPM1 | c.1065C>G p.I355M | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV99856672; called by muse, mutect2
- XAB2 | c.1630G>A p.G544S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs185125117, COSV99352009; called by muse, mutect2, varscan2
- ZSCAN22 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 60/78 reads (77%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs568354675, COSV61639700; called by muse, mutect2, varscan2
- COL2A1 | c.3282dup p.G1095Rfs*23 | Frame Shift Ins (INS) | VAF 15/45 reads (33%) | called by mutect2, pindel, varscan2
- FAM47B | c.350del p.F117Sfs*2 | Frame Shift Del (DEL) | VAF 71/127 reads (56%) | called by mutect2, pindel, varscan2
- IGHV3-38 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- LHX2 | c.173del p.G58Afs*71 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | called by mutect2, pindel, varscan2
- PTEN | c.956_960del p.T319Nfs*4 | Frame Shift Del (DEL) | VAF 48/66 reads (73%) | called by mutect2, pindel, varscan2
- RUSC1 | c.2263_2273del p.P755Wfs*5 (on ENST00000368352 / NM_001105203.2; = p.P286Wfs*5 on NM_014328.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 23/41 reads (56%) | called by mutect2, pindel, varscan2
- SPINK5 | c.1645_1647del p.E549del | In Frame Del (DEL) | VAF 10/38 reads (26%) | called by pindel, varscan2
- AMER1 | c.2073C>T p.S691= | Silent (SNP) | VAF 48/139 reads (35%) | catalogued as rs150875520, COSV100367058; called by muse, mutect2, varscan2
- ATP2B3 | c.2790G>C p.L930= | Silent (SNP) | VAF 71/181 reads (39%) | catalogued as rs781943907, COSV99685865; called by muse, mutect2, varscan2
- BPIFB3 | c.54G>A p.A18= | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as rs759548237, COSV64957491; called by muse, mutect2
- DLX1 | c.45G>C p.S15= | Silent (SNP) | VAF 53/114 reads (46%) | catalogued as COSV100250145; called by muse, mutect2, varscan2
- INAVA | c.444G>A p.T148= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs773426005, COSV100950123; called by muse, varscan2
- NSD2 | c.618T>G p.S206= | Silent (SNP) | VAF 73/100 reads (73%) | catalogued as COSV100373920; called by muse, mutect2, varscan2
- NUP210 | c.798C>T p.I266= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV99597050; called by muse, mutect2, varscan2
- RBM15 | c.1854G>T p.R618= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV100873514; called by muse, mutect2, varscan2
- SMPDL3B | c.201C>G p.P67= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100875390; called by muse, mutect2, varscan2
- ZEB2 | c.3279C>T p.R1093= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100356921; called by muse, mutect2, varscan2
